Somatic mutation profile of tumor specimen TCGA-3S-AAYX-01A (aliquot TCGA-3S-AAYX-01A-11D-A423-09) from TCGA case TCGA-3S-AAYX, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 55.7 years (20,350 days).
Specimen TCGA-3S-AAYX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f70a4d9c-1f42-4a86-a984-5e910bf25cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3S-AAYX-10A (Blood Derived Normal), aliquot TCGA-3S-AAYX-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/81dbba00-17db-484c-bd8b-920076e70a1e

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Del 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR139 | c.730del p.R244Afs*4 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | catalogued as COSV58505701; called by mutect2, pindel, varscan2
- PLCG1 | c.1303del p.D435Tfs*45 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2
- RPL11 | c.140C>G p.P47R (on ENST00000374550 / NM_001199802.1; = p.P48R on NM_000975.5) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2
